Somatic mutation profile of tumor specimen TCGA-RG-A7D4-01A (aliquot TCGA-RG-A7D4-01A-12D-A33Q-10) from TCGA case TCGA-RG-A7D4, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 69.3 years (25,302 days).
Specimen TCGA-RG-A7D4-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 98afc2af-9e82-4025-8174-cc25701dc6e9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-RG-A7D4-10A (Blood Derived Normal), aliquot TCGA-RG-A7D4-10A-01D-A33Q-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/359400ee-9425-41bc-82d6-d7538b72ab85

The open-access MAF lists 109 somatic variants for this specimen: 80 protein-altering or splice-affecting, 28 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 69, Silent 28, Frame Shift Del 6, Splice Site 3, Nonsense Mutation 1, RNA 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.133T>C p.S45P | Missense Mutation (SNP) | VAF 57/151 reads (38%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as rs121913407, COSV62687880, COSV62689248, COSV62696859; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.824G>A p.C275Y | Missense Mutation (SNP) | VAF 15/50 reads (30%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs863224451, CM076568, CM951234, COSV52661919, COSV52663595, COSV52675710, COSV52772708; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADGRV1 | c.5873C>T p.S1958F | Missense Mutation (SNP) | VAF 37/103 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.62); catalogued as COSV67980197; called by muse, mutect2, varscan2
- ADH1B | c.829-1G>A p.X277_splice | Splice Site (SNP) | VAF 7/58 reads (12%) | catalogued as rs1387786398, COSV59295497; called by muse, mutect2, varscan2
- ADNP2 | c.3217A>G p.I1073V | Missense Mutation (SNP) | VAF 4/62 reads (6%) | SIFT tolerated (0.65); PolyPhen benign (0.003); catalogued as rs1017394520, COSV51536981; called by muse, mutect2
- AFTPH | c.1318T>G p.S440A | Missense Mutation (SNP) | VAF 5/67 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV53216520; called by muse, mutect2
- APBB1 | c.1724G>A p.R575H | Missense Mutation (SNP) | VAF 3/48 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.825); catalogued as rs1046276459, COSV100192345; called by muse, mutect2
- ATG4C | c.877G>T p.V293F | Missense Mutation (SNP) | VAF 26/108 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.337); catalogued as COSV58604269; called by muse, mutect2, varscan2
- CCR6 | c.797G>A p.C266Y | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.61); catalogued as COSV59474257; called by muse, mutect2, varscan2
- CD69 | c.533A>C p.N178T | Missense Mutation (SNP) | VAF 14/116 reads (12%) | SIFT tolerated (0.28); PolyPhen benign (0.013); catalogued as COSV57302448; called by muse, mutect2, varscan2
- CFAP43 | c.2481A>C p.E827D | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.334); catalogued as COSV53376840; called by muse, mutect2, varscan2
- CHST1 | c.901C>T p.R301C | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57322473; called by muse, mutect2, varscan2
- CHST3 | c.1109G>A p.R370H | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100910392; called by muse, mutect2
- CLSTN3 | c.1807A>G p.T603A | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV56934596; called by muse, mutect2, varscan2
- CNTN1 | c.2930G>A p.R977H | Missense Mutation (SNP) | VAF 31/107 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61637208; called by muse, mutect2, varscan2
- COL5A1 | c.4555-2A>T p.X1519_splice | Splice Site (SNP) | VAF 9/28 reads (32%) | catalogued as COSV65666403; called by muse, mutect2, varscan2
- CTR9 | c.1126G>A p.E376K | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs869312709, COSV63727939; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DCAF12 | c.1085T>C p.L362P | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63511808; called by muse, mutect2, varscan2
- DEPDC5 | c.2185C>T p.L729F (on ENST00000400246; = p.L798F on NM_014662.5) | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56692852; called by muse, mutect2, varscan2
- DLEC1 | c.4556G>A p.R1519Q | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.059); catalogued as rs370658013; called by muse, mutect2, varscan2
- FAM171A1 | c.2357C>T p.T786M | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1281476146, COSV65314280; called by muse, mutect2, varscan2
- FAT4 | c.4135G>T p.D1379Y | Missense Mutation (SNP) | VAF 20/90 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67882615; called by muse, mutect2, varscan2
- FAT4 | c.11014T>C p.S3672P | Missense Mutation (SNP) | VAF 4/51 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.122); catalogued as COSV58675290; called by muse, mutect2
- GLUD2 | c.533C>G p.P178R | Missense Mutation (SNP) | VAF 25/43 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1366485762, COSV100046561, COSV60151499; called by muse, mutect2, varscan2
- GPR137 | c.823G>A p.V275I | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.147); catalogued as rs762903268, COSV57401303; called by muse, mutect2, varscan2
- IGHV3-13 | c.306C>G p.N102K | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.286); catalogued as rs370967026; called by muse, mutect2, varscan2
- LCE1E | c.245A>G p.H82R | Missense Mutation (SNP) | VAF 82/176 reads (47%) | SIFT tolerated, low confidence (0.78); PolyPhen benign (0); catalogued as rs772855523, COSV64219618; called by muse, mutect2, varscan2
- LCMT2 | c.1601G>T p.R534L | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV59789792; called by muse, mutect2, varscan2
- LCP2 | c.876A>C p.E292D | Missense Mutation (SNP) | VAF 50/144 reads (35%) | SIFT tolerated (0.69); PolyPhen benign (0.001); catalogued as COSV50447483; called by muse, mutect2, varscan2
- LHFPL5 | c.84G>A p.M28I | Missense Mutation (SNP) | VAF 41/130 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.06); catalogued as rs370902662; called by muse, mutect2, varscan2
- LRSAM1 | c.1012C>T p.R338W | Missense Mutation (SNP) | VAF 12/142 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs774505948, COSV55938814; called by muse, mutect2
- MBTPS1 | c.1190G>C p.G397A | Missense Mutation (SNP) | VAF 11/116 reads (9%) | SIFT tolerated (0.41); PolyPhen benign (0.05); catalogued as COSV58569853; called by muse, mutect2, varscan2
- MSTN | c.1007C>G p.A336G | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.057); catalogued as COSV53620457; called by muse, mutect2, varscan2
- MTMR9 | c.812A>T p.Y271F | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated (0.7); PolyPhen benign (0.001); catalogued as COSV55311087; called by muse, mutect2, varscan2
- MYO5A | c.3311A>G p.H1104R | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV62557643; called by muse, mutect2, varscan2
- NCAPD3 | c.4036C>T p.P1346S | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV73187767; called by muse, mutect2, varscan2
- NCAPH | c.790A>G p.T264A | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT tolerated (0.31); PolyPhen benign (0.393); catalogued as rs1475474227, COSV53635452; called by muse, mutect2, varscan2
- NID1 | c.1555C>T p.Q519* | Nonsense Mutation (SNP) | VAF 25/58 reads (43%) | catalogued as COSV51616324; called by muse, mutect2, varscan2
- NIN | c.1582C>A p.L528M | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV55400488, COSV99811709; called by muse, mutect2, varscan2
- NIN | c.1581C>A p.F527L | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.99); catalogued as COSV99811717; called by muse, mutect2, varscan2
- NRAP | c.4996G>A p.G1666S (on ENST00000359988 / NM_001322945.2; = p.G1631S on NM_006175.4) | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV63489044; called by muse, mutect2, varscan2
- OR4K17 | c.296C>A p.T99N | Missense Mutation (SNP) | VAF 18/89 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.753); catalogued as COSV59647501; called by muse, mutect2, varscan2
- OR8B4 | c.734T>A p.I245N | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.814); catalogued as COSV62069404, COSV99049624; called by muse, mutect2, varscan2
- PALM | c.907A>G p.M303V | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1381627131, COSV52767072; called by muse, mutect2, varscan2
- PCDH18 | c.2424C>G p.I808M | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.896); catalogued as COSV61266966; called by muse, mutect2, varscan2
- PCDHGA4 | c.2479G>T p.D827Y | Missense Mutation (SNP) | VAF 54/156 reads (35%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.922); catalogued as rs745537699, COSV53913204, COSV99549371; called by muse, mutect2, varscan2
- PDCD11 | c.2738A>T p.D913V | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.04); catalogued as COSV63933294; called by muse, mutect2, varscan2
- PLEKHA6 | c.3118G>T p.A1040S | Missense Mutation (SNP) | VAF 14/154 reads (9%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.108); catalogued as COSV55331240; called by muse, mutect2
- POC5 | c.1504A>C p.I502L (on ENST00000428202 / NM_001099271.2; = p.I477L on NM_152408.2) | Missense Mutation (SNP) | VAF 28/99 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.104); catalogued as COSV66841819; called by muse, mutect2, varscan2
- PPFIA2 | c.1872T>A p.D624E | Missense Mutation (SNP) | VAF 37/110 reads (34%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.98); catalogued as COSV61023933; called by muse, mutect2, varscan2
- PREX2 | c.2741C>T p.A914V | Missense Mutation (SNP) | VAF 5/94 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV55757202; called by muse, mutect2
- PRKDC | c.4779G>A p.V1593= | Splice Region (SNP) | VAF 10/56 reads (18%) | catalogued as rs1300094473, COSV58046415; called by muse, mutect2
- PTGER2 | c.412A>G p.I138V | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.506); catalogued as COSV55418376; called by muse, mutect2, varscan2
- PTPRB | c.4102T>C p.S1368P | Missense Mutation (SNP) | VAF 6/75 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54235861; called by muse, mutect2
- PUM1 | c.2048C>T p.A683V | Missense Mutation (SNP) | VAF 14/126 reads (11%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.772); catalogued as COSV57082649; called by muse, mutect2, varscan2
- RASSF10 | c.741C>G p.H247Q | Missense Mutation (SNP) | VAF 31/111 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.054); catalogued as rs374969897; called by muse, mutect2, varscan2
- REV3L | c.373A>G p.I125V | Missense Mutation (SNP) | VAF 53/221 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.172); catalogued as rs901005247, COSV62616450; called by muse, mutect2, varscan2
- RYR3 | c.358C>A p.L120I | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66781245; called by muse, mutect2, varscan2
- SIK3 | c.3367C>T p.H1123Y (on ENST00000445177 / NM_001366686.2; = p.H1081Y on NM_025164.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.377); catalogued as COSV52610492; called by muse, mutect2, varscan2
- SLC22A15 | c.775A>C p.S259R | Missense Mutation (SNP) | VAF 19/94 reads (20%) | SIFT tolerated (0.36); PolyPhen benign (0.009); catalogued as COSV65677502; called by muse, mutect2, varscan2
- SLC25A32 | c.97G>A p.G33S | Missense Mutation (SNP) | VAF 95/163 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52566987; called by muse, mutect2, varscan2
- SNX15 | c.400G>T p.V134L | Missense Mutation (SNP) | VAF 8/108 reads (7%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV57246143; called by muse, mutect2
- STAB2 | c.7489-1G>C p.X2497_splice | Splice Site (SNP) | VAF 21/73 reads (29%) | catalogued as COSV66335791; called by muse, mutect2, varscan2
- STXBP4 | c.1384A>G p.T462A | Missense Mutation (SNP) | VAF 45/124 reads (36%) | SIFT tolerated (0.5); PolyPhen benign (0.026); catalogued as COSV64463917; called by muse, mutect2, varscan2
- TAMM41 | c.656T>C p.I219T | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.953); catalogued as COSV56070985; called by muse, mutect2, varscan2
- TCF23 | c.95G>A p.R32K | Missense Mutation (SNP) | VAF 6/108 reads (6%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV56078065; called by muse, mutect2
- TGOLN2 | c.697G>A p.D233N | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.941); catalogued as COSV56405491; called by muse, mutect2, varscan2
- TMEM132D | c.1488G>T p.M496I | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.647); catalogued as COSV67159259; called by muse, mutect2, varscan2
- TRPM8 | c.1988C>T p.A663V | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.177); catalogued as COSV61221078; called by muse, mutect2, varscan2
- TTN | c.78799G>A p.E26267K (on ENST00000591111; = p.E18843K on NM_003319.4) | Missense Mutation (SNP) | VAF 17/63 reads (27%) | PolyPhen benign (0.167); catalogued as COSV59933576; called by muse, mutect2, varscan2
- USH2A | c.15092G>T p.R5031L | Missense Mutation (SNP) | VAF 16/145 reads (11%) | SIFT tolerated (0.3); PolyPhen benign (0.011); catalogued as COSV100240873, COSV56339321; called by muse, mutect2, varscan2
- USP32 | c.3936G>T p.L1312F | Missense Mutation (SNP) | VAF 81/155 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV56265457; called by muse, mutect2, varscan2
- ZNFX1 | c.4699A>G p.M1567V | Missense Mutation (SNP) | VAF 33/68 reads (49%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV65595049; called by muse, mutect2, varscan2
- ADAMTSL1 | c.4429del p.V1477Cfs*8 | Frame Shift Del (DEL) | VAF 15/92 reads (16%) | called by mutect2, pindel, varscan2
- ASPRV1 | c.465_514del p.Q156Wfs*22 | Frame Shift Del (DEL) | VAF 34/90 reads (38%) | called by mutect2, pindel
- CLDN12 | c.598_602del p.K200Ffs*33 | Frame Shift Del (DEL) | VAF 8/58 reads (14%) | called by mutect2, pindel, varscan2
- CNTROB | c.2458_2476del p.G820Ifs*6 | Frame Shift Del (DEL) | VAF 31/103 reads (30%) | called by mutect2, pindel, varscan2
- IGLV2-23 | c.101G>A p.G34E | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.805); called by muse, mutect2, varscan2
- MRPS5 | c.949del p.H317Tfs*75 | Frame Shift Del (DEL) | VAF 5/48 reads (10%) | called by mutect2, varscan2
- RTKN2 | c.949del p.L317Sfs*19 | Frame Shift Del (DEL) | VAF 36/138 reads (26%) | called by mutect2, pindel, varscan2
- AHNAK | c.9831A>G p.K3277= | Silent (SNP) | VAF 3/45 reads (7%) | catalogued as COSV99945650; called by muse, mutect2
- ANK2 | c.6135A>G p.T2045= | Silent (SNP) | VAF 39/143 reads (27%) | catalogued as COSV52150689; called by muse, mutect2, varscan2
- ARFGEF3 | c.3780C>T p.F1260= | Silent (SNP) | VAF 8/94 reads (9%) | catalogued as rs777169557, COSV52451201; called by muse, mutect2
- CYB5D2 | c.462G>A p.A154= | Silent (SNP) | VAF 40/104 reads (38%) | catalogued as rs748080113, COSV56800345; called by muse, mutect2, varscan2
- DHX15 | c.2253A>T p.T751= | Silent (SNP) | VAF 10/117 reads (9%) | catalogued as COSV61026004; called by muse, mutect2
- DNAH5 | c.10320C>A p.A3440= | Silent (SNP) | VAF 4/98 reads (4%) | catalogued as COSV99445302; called by muse, mutect2
- EGFLAM | c.1296C>T p.H432= | Silent (SNP) | VAF 13/62 reads (21%) | catalogued as rs375160813; called by muse, mutect2, varscan2
- FCRL6 | c.273A>C p.P91= | Silent (SNP) | VAF 131/295 reads (44%) | catalogued as COSV58940339; called by muse, mutect2, varscan2
- FLG | c.7806C>A p.G2602= | Silent (SNP) | VAF 54/157 reads (34%) | catalogued as COSV64238243; called by muse, mutect2, varscan2
- FOXI1 | c.795G>A p.E265= | Silent (SNP) | VAF 18/153 reads (12%) | catalogued as rs756749477, COSV60388243; called by muse, mutect2, varscan2
- IFNA10 | c.237C>T p.V79= | Silent (SNP) | VAF 12/137 reads (9%) | catalogued as COSV53330646; called by muse, mutect2
- KIF11 | c.1080G>A p.L360= | Silent (SNP) | VAF 8/64 reads (13%) | catalogued as COSV53269281; called by muse, mutect2
- MCHR1 | c.285G>T p.S95= | Silent (SNP) | VAF 20/59 reads (34%) | catalogued as rs201514957, COSV50760533; called by muse, mutect2, varscan2
- MYOM1 | c.2310G>T p.G770= | Silent (SNP) | VAF 81/185 reads (44%) | catalogued as rs769216946, COSV55287059; called by muse, mutect2, varscan2
- NLRP14 | c.528A>G p.P176= | Silent (SNP) | VAF 23/97 reads (24%) | catalogued as rs768980030, COSV55064927; called by muse, mutect2, varscan2
- NRP2 | c.423C>A p.I141= | Silent (SNP) | VAF 16/52 reads (31%) | catalogued as COSV55924671; called by muse, mutect2, varscan2
- NUBPL | c.33T>C p.G11= | Silent (SNP) | VAF 6/29 reads (21%) | catalogued as COSV55266345, COSV55269277; called by muse, mutect2, varscan2
- OR4A5 | c.835C>T p.L279= | Silent (SNP) | VAF 14/78 reads (18%) | catalogued as rs1213674443, COSV60521871; called by muse, mutect2, varscan2
- PIKFYVE | c.5964A>G p.L1988= | Silent (SNP) | VAF 22/90 reads (24%) | catalogued as rs774554872, COSV52238271; called by muse, mutect2, varscan2
- PLXNA3 | c.1722C>T p.C574= | Silent (SNP) | VAF 3/37 reads (8%) | catalogued as COSV100859812; called by muse, mutect2
- RELA | c.1416C>A p.S472= | Silent (SNP) | VAF 19/67 reads (28%) | catalogued as COSV58014077; called by muse, mutect2, varscan2
- SLF1 | c.1986A>G p.S662= | Silent (SNP) | VAF 14/63 reads (22%) | catalogued as COSV54368208; called by muse, mutect2, varscan2
- SLIT3 | c.3021C>T p.N1007= | Silent (SNP) | VAF 31/72 reads (43%) | catalogued as COSV60596507; called by muse, mutect2, varscan2
- TRAV26-1 | c.274C>T p.L92= | Silent (SNP) | VAF 8/18 reads (44%) | called by muse, mutect2, varscan2
- UGT2A2 | c.636G>A p.Q212= | Silent (SNP) | VAF 22/187 reads (12%) | catalogued as rs894523773, COSV54139206; called by muse, mutect2, varscan2
- VPS13A | c.198A>G p.K66= | Silent (SNP) | VAF 50/214 reads (23%) | catalogued as COSV62426360; called by muse, mutect2, varscan2
- ZC2HC1A | c.342T>C p.S114= | Silent (SNP) | VAF 34/258 reads (13%) | catalogued as COSV55667614; called by muse, mutect2, varscan2
- ZNF683 | c.159T>C p.H53= | Silent (SNP) | VAF 19/77 reads (25%) | catalogued as COSV62873661; called by muse, mutect2, varscan2
- LINC01565 | n.1051C>T | RNA (SNP) | VAF 23/107 reads (21%) | called by muse, mutect2, varscan2
